Somatic mutation profile of tumor specimen 0DXMM4 from CCDI case PBCPEK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 0.9 years (319 days).
Specimen 0DXMM4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 444f88e0-dc8f-4c43-a244-8ec954efa458.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXMLT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e347fcbf-72d6-49e8-966a-32a8b1b2e83f

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Nonsense Mutation 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.49804C>A p.Q16602K (on ENST00000591111; = p.Q9178K on NM_003319.4) | Missense Mutation (SNP) | VAF 282/960 reads (29%) | PolyPhen benign (0.337); catalogued as COSV59994382; called by muse, mutect2, varscan2
- ADH7 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 461/816 reads (56%) | called by muse, mutect2, varscan2
- COL1A2 | c.282C>G p.G94= | Splice Region (SNP) | VAF 127/612 reads (21%) | called by muse, mutect2, varscan2
- GJB6 | c.746C>A p.S249* | Nonsense Mutation (SNP) | VAF 33/630 reads (5%) | called by muse, mutect2
- MAPK8IP1 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 23/420 reads (5%) | called by muse, mutect2
- NR2F6 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POTEH | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 56/1056 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2
- ZFYVE16 | c.3557C>A p.A1186E | Missense Mutation (SNP) | VAF 21/784 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MRM3 | c.1083C>T p.G361= | Silent (SNP) | VAF 352/828 reads (43%) | catalogued as rs1422775072; called by muse, mutect2, varscan2
- NOTCH1 | c.1356C>T p.D452= | Silent (SNP) | VAF 138/313 reads (44%) | catalogued as rs767527946, COSV53071116; called by muse, mutect2, varscan2
- PLEC | c.5166C>T p.F1722= (on ENST00000322810 / NM_201380.4; = p.F1612= on NM_000445.5) | Silent (SNP) | VAF 107/259 reads (41%) | catalogued as rs782561083; called by muse, mutect2, varscan2
- TCP11L2 | c.15C>A p.G5= | Silent (SNP) | VAF 167/502 reads (33%) | catalogued as COSV54430767; called by muse, mutect2, varscan2
- ITGA2B | c.2728-30G>A | Intron (SNP) | VAF 8/175 reads (5%) | catalogued as rs1213199008; called by muse, mutect2
